TARGET case TARGET-15-SJMPAL043773 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0cff5450-2ad5-41e6-8033-00d1998b1cda

Demographics
Sex at birth: female; Age at index: 7 years; Vital status: Dead; Days to death: 394 days (1.1 years).

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 7.5 years (2,743 days); Year of diagnosis: 2007; Days to last follow up: 394 days (1.1 years).

Follow-up (1 entry)
- Days to follow up: 394 days (1.1 years); Event-free: no event (relapse, second malignancy or death) recorded through day 394; Year of follow up: 2008.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 0: Leukocytes 35 ×10³/µL.

Biospecimens (4 samples)
- Samples TARGET-15-SJMPAL043773-03A, TARGET-15-SJMPAL043773-03B (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
- Sample TARGET-15-SJMPAL043773-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.
- Sample TARGET-15-SJMPAL043773-40A: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 394
- Protocol: St. Jude
- WBC at Diagnosis: 35
- Initial Therapy: AML
- Karyotype: 45,xx,add(1)(p36),der(5)t(5;7)(q11.2;p13),+der(5)t(5;7)(q11.2;p13),der(7)(7qter>7q21::7p15>7q21::5q11.2>5qter),-11,add(13)(p11.2),-17,der(22)t(11;22)(q13;q13)[20]
- WHO ALAL Classification: T/M
- WHO Dx: T/M
- WHO RL1: T/M
